Gene-level copy-number profile of tumor specimen ALCH-ADUX-TTP1-A from ALCHEMIST case ALCH-ADUX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 56.3 years (20,571 days).
Specimen ALCH-ADUX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1d0d7719-9f25-47c8-85c6-67be2fdcff13.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADUX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/be334581-492e-4ee4-aeeb-747bf9185e42

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 198; copy number 1: 6,696; copy number 2: 51,287; copy number 3: 672; copy number 4: 40; copy number 5: 8.

Homozygous deletions (total copy number 0; autosomes only): 113 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,309,230–91,685,884, 9 genes: AC233263.2, IGKV1OR2-118, AC233263.1, AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1.
- chr2:91,775,944–91,781,169, 1 gene: GGT8P.
- chr3:47,802,909–47,850,195, 3 genes (within-gene range 0–1): DHX30, AC026318.1, MIR1226.
- chr4:56,794,348–56,821,742, 5 genes: RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA.
- chr5:69,631,963–69,636,399, 1 gene: AC139495.2.
- chr5:177,476,631–177,497,606, 2 genes (within-gene range 0–1): AC145098.2, PDLIM7.
- chr7:6,923,804–6,939,603, 3 genes: ALG1L5P, AC079804.1, FAM86LP.
- chr10:68,414,064–68,472,121, 3 genes (within-gene range 0–1): DNA2, RPL26P29, RNA5SP319.
- chr10:86,654,547–86,736,072, 2 genes: OPN4, LDB3.
- chr10:100,042,193–100,081,869, 1 gene: CPN1.
- chr11:72,685,075–72,693,808, 1 gene (within-gene range 0–1): ARAP1-AS1.
- chr11:72,700,474–72,705,607, 1 gene (within-gene range 0–1): ARAP1-AS2.
- chr11:73,376,399–73,397,474, 2 genes: RELT, AP000763.4.
- chr15:23,430,839–23,447,243, 2 genes: HERC2P6, GOLGA6L2.
- chr15:25,170,723–25,187,616, 10 genes (within-gene range 0–2): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10.
- chr15:25,194,921–25,250,940, 31 genes (within-gene range 0–2): SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:73,335,260–73,342,387, 1 gene (within-gene range 0–2): AC068397.2.
- chr16:46,469,341–46,931,289, 18 genes: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2.
- chr16:83,899,115–83,966,332, 3 genes (within-gene range 0–2): MLYCD, AC009119.2, OSGIN1.
- chr16:84,009,667–84,045,333, 3 genes: SLC38A8, RNA5SP432, AC040169.4.
- chr17:877,902–880,093, 1 gene (within-gene range 0–1): AC087392.2.
- chr17:61,393,456–61,411,555, 1 gene (within-gene range 0–1): TBX2-AS1.
- chr17:61,411,751–61,413,280, 1 gene: LINC02875.
- chr19:39,863,323–39,934,626, 1 gene: FCGBP.
- chr20:267,186–300,321, 3 genes: AL034548.1, C20orf96, ZCCHC3.
- chr20:3,208,868–3,245,382, 3 genes: ITPA, SLC4A11, AL109976.1.
- chr20:3,846,799–3,876,123, 1 gene: MAVS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:118,193,725–118,266,817, 5 genes, copy number 5: JAML, HSPE1P18, MPZL3, MPZL2, AP002800.1.
- chr20:62,872,250–62,937,952, 3 genes, copy number 5: ARF4P2, DIDO1, AL117379.1.

Autosomal genes at a single copy (total copy number 1): 3,926. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
